BEATAML1.0 case 2806 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myelodysplastic Syndromes; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/b3a84587-45bb-47d5-b907-87e1f41edf8a

Demographics
Sex at birth: male; Race: white; Vital status: Dead.

Diagnoses (1)
1. Refractory cytopenia with multilineage dysplasia: ICD-O-3 morphology code: 9985/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.4 years (26,430 days); Progression or recurrence: no.

Biospecimens (3 samples)
- Sample BA3260D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample BA3260R: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Fresh.
- Sample BA3382D: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
